Somatic mutation profile of tumor specimen TCGA-IN-A7NU-01A (aliquot TCGA-IN-A7NU-01A-22D-A34U-08) from TCGA case TCGA-IN-A7NU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 69.9 years (25,515 days).
Specimen TCGA-IN-A7NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ecf7350-b90a-4212-8c93-82ab724bfbd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A7NU-10A (Blood Derived Normal), aliquot TCGA-IN-A7NU-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d12ea02-633f-4598-a813-ef83d3a1b1be

The open-access MAF lists 103 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 26, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, 3'Flank 1, Frame Shift Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAT2 | c.195T>A p.C65* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as COSV100887177; called by muse, mutect2, varscan2
- ACBD3 | c.429-1G>A p.X143_splice | Splice Site (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100830994, COSV100831108; called by muse, mutect2, varscan2
- ACSS3 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99699271; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5012G>T p.R1671I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs1284876893, COSV101000892; called by muse, mutect2
- ANKRD35 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs371562465; called by muse, mutect2, varscan2
- APOB | c.10729T>A p.F3577I | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV99267097; called by muse, mutect2, varscan2
- ARHGAP29 | c.676G>T p.V226F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99558705; called by muse, mutect2, varscan2
- CACNA2D1 | c.320T>G p.V107G | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV100667040; called by muse, mutect2, varscan2
- CD1E | c.409T>G p.F137V | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100937043; called by muse, mutect2, varscan2
- CDH11 | c.1618A>G p.N540D | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1292355009, COSV51776267, COSV99219378; called by muse, mutect2, varscan2
- COL4A1 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771281179, COSV101011408; called by muse, varscan2
- CPB1 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99294447; called by muse, mutect2, varscan2
- DOCK4 | c.274A>C p.T92P | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV101455664; called by muse, mutect2, varscan2
- DST | c.3629A>G p.N1210S (on ENST00000361203 / NM_001374722.1; = p.N884S on NM_001723.6) | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99758742; called by muse, mutect2, varscan2
- ERICH3 | c.3293T>G p.L1098R | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1442657117, COSV100444099, COSV100445208; called by muse, mutect2, varscan2
- FAM174A | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs190913300, COSV100444552; called by muse, mutect2, varscan2
- FLG | c.11832A>G p.I3944M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); catalogued as COSV100911932; called by muse, mutect2, varscan2
- FOXP2 | c.1667T>G p.L556R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100646527, COSV100646883; called by muse, mutect2, varscan2
- GALNT18 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.146); catalogued as COSV99925455; called by muse, mutect2, varscan2
- GPR22 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV99772799; called by muse, mutect2, varscan2
- HEXD | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs983012352, COSV100027946; called by muse, mutect2
- HMCN1 | c.16797A>C p.E5599D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99633549; called by muse, mutect2, varscan2
- HSPA2 | c.1912G>A p.V638M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.969); catalogued as COSV99905086; called by muse, mutect2
- IGSF9B | c.3466G>A p.G1156R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as rs764131054, COSV100318199; called by muse, mutect2, varscan2
- IKZF1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58787727; called by muse, mutect2, varscan2
- IL7 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99805507; called by muse, mutect2, varscan2
- INPP1 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59416909; called by muse, mutect2
- INPP1 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100487300; called by muse, mutect2
- INPP5B | c.1970G>C p.R657P (on ENST00000373023; = p.R577P on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100886561, COSV65960360; called by muse, mutect2, varscan2
- KANK4 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62985195, COSV62988001; called by muse, mutect2, varscan2
- KCNN2 | c.712A>G p.T238A (on ENST00000264773; = p.T450A on NM_021614.4) | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV99300401; called by muse, mutect2, varscan2
- KMT2C | c.10088G>A p.C3363Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.223); catalogued as COSV100074994; called by muse, mutect2, varscan2
- LRP1B | c.3932G>A p.R1311K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101259175, COSV67263275; called by muse, mutect2, varscan2
- LRRC45 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373267378; called by muse, mutect2, varscan2
- MAGEE1 | c.1912T>A p.L638I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100819481, COSV63909373; called by muse, mutect2, varscan2
- MRC1 | c.669C>A p.D223E | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100509653; called by muse, mutect2, varscan2
- MYLPF | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1355062107, COSV100363145; called by muse, mutect2, varscan2
- NCOR1 | c.4252C>T p.P1418S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV99251393; called by muse, mutect2, varscan2
- NPAT | c.2252C>G p.S751C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99586247; called by muse, mutect2
- OR10G8 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368438499; called by muse, mutect2, varscan2
- OR10S1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs768732449, COSV73342833; called by muse, mutect2, varscan2
- PCDH17 | c.2238G>T p.E746D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV100931816; called by muse, mutect2, varscan2
- PCDHGA1 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as rs1316392656, COSV65295964; called by muse, mutect2, varscan2
- PDE3B | c.2678C>T p.T893M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201854538, COSV56386989; called by muse, mutect2, varscan2
- PHACTR3 | c.1384+2T>A p.X462_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100732293, COSV100732985; called by muse, mutect2, varscan2
- PPP6R3 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs548544943, COSV99677138; called by muse, mutect2, varscan2
- PRAMEF4 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99340034; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1892T>A p.L631Q (on ENST00000352766; = p.L552Q on NM_181334.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV100424551; called by muse, mutect2, varscan2
- PTBP2 | c.577A>C p.I193L (on ENST00000426398 / NM_001300986.2; = p.I185L on NM_021190.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100930252; called by muse, mutect2, varscan2
- PTP4A3 | c.116A>C p.K39T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100267403; called by muse, mutect2
- RD3 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV100879225; called by muse, mutect2
- RHBDL3 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99283843; called by muse, mutect2, varscan2
- RIMS2 | c.874A>G p.S292G (on ENST00000666250 / NM_001348490.2; = p.S100G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.006); catalogued as COSV99180335, COSV99214079; called by muse, mutect2, varscan2
- RMND5A | c.695A>C p.Q232P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV99373892; called by muse, mutect2, varscan2
- RPH3A | c.1313C>T p.P438L (on ENST00000389385 / NM_001143854.2; = p.P434L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1412088902, COSV101231872, COSV66991094; called by muse, mutect2, varscan2
- RYR3 | c.5209G>A p.V1737M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as rs561525049, COSV66807305; ClinVar: uncertain significance; called by mutect2, varscan2
- SLC13A1 | c.716T>A p.L239H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.935); catalogued as COSV52014805, COSV99521317, COSV99521640; called by muse, mutect2, varscan2
- SLC6A1 | c.1651T>C p.Y551H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV99823052; called by muse, mutect2, varscan2
- SMARCA2 | c.1337A>G p.Q446R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100571429; called by muse, mutect2, varscan2
- SMARCC1 | c.3087G>A p.M1029I | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99593276; called by muse, mutect2, varscan2
- SOGA3 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100847014; called by muse, mutect2, varscan2
- STAT4 | c.1562A>G p.K521R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100636134; called by muse, mutect2, varscan2
- TLR4 | c.506A>T p.E169V (on ENST00000355622 / NM_138554.5; = p.E129V on NM_003266.4) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as COSV100790679, COSV62922393; called by muse, mutect2, varscan2
- TRIM65 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99485549; called by muse, mutect2, varscan2
- UBE2E2 | c.116A>C p.K39T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV100233522; called by muse, mutect2, varscan2
- XKR8 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); catalogued as COSV100872142; called by muse, mutect2, varscan2
- ZNF131 | c.1158dup p.G387Rfs*16 (on ENST00000509156 / NM_001330707.2; = p.G353Rfs*16 on NM_003432.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | catalogued as rs761039969; called by mutect2, varscan2
- ZNF415 | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99701842; called by muse, mutect2, varscan2
- ZNF423 | c.1835G>A p.S612N (on ENST00000563137 / NM_001379286.1; = p.S604N on NM_015069.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs1464787963, COSV99283097; called by muse, mutect2, varscan2
- ZNF683 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758681579, COSV62875624; called by muse, mutect2
- ARID2 | c.4883del p.P1628Lfs*73 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- ZNF267 | c.1239_1240del p.C413Wfs*7 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by pindel, varscan2
- AC004997.1 | c.978G>A p.L326= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV53163229; called by muse, mutect2
- ACSS3 | c.1554G>A p.K518= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs768212741, COSV99699274; called by muse, mutect2, varscan2
- ADAMTS5 | c.298T>C p.L100= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV99538122; called by muse, mutect2
- ANKS4B | c.999C>T p.D333= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs764834931, COSV100289886; called by muse, mutect2, varscan2
- CCL5 | c.105T>C p.F35= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CDC25C | c.393G>A p.P131= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs777224883, COSV60398472; called by muse, mutect2, varscan2
- CDH18 | c.591G>T p.V197= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV99937290; called by muse, mutect2, varscan2
- CLN8 | c.660C>T p.D220= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs768136048, COSV58669868, COSV58670579; called by muse, mutect2, varscan2
- CTNNA2 | c.510A>G p.Q170= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100785447; called by muse, mutect2, varscan2
- DDAH2 | c.807C>T p.G269= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs766268044, COSV65383569; called by muse, mutect2, varscan2
- DNHD1 | c.1260G>C p.V420= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99600710; called by muse, mutect2
- DSTN | c.69C>T p.C23= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99855245; called by muse, mutect2, varscan2
- FZD10 | c.1731G>A p.S577= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1342614836, COSV57473029; called by muse, mutect2
- LIPC | c.420G>T p.V140= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100134787; called by muse, mutect2
- LRP4 | c.762G>A p.A254= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs759453211, COSV101066642; called by muse, mutect2, varscan2
- MXRA5 | c.1989G>A p.T663= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs368514114, COSV54250797; called by muse, mutect2, varscan2
- NGFR | c.384C>T p.C128= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1452545832, COSV99413000; called by muse, mutect2, varscan2
- OR1A1 | c.129G>T p.L43= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV100410803; called by muse, mutect2, varscan2
- OTUD6A | c.213C>T p.S71= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs748197149, COSV57973872; called by muse, mutect2, varscan2
- P2RY12 | c.705C>T p.N235= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs766571463, COSV56395696; called by muse, mutect2, varscan2
- PCDHB12 | c.1596C>T p.G532= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99507615; called by muse, mutect2, varscan2
- SGCG | c.660G>A p.A220= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs550268354, COSV54561001; called by muse, mutect2, varscan2
- TPR | c.324C>T p.A108= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs1273170170, COSV99834454; called by mutect2, varscan2
- TTC39B | c.1518C>T p.A506= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs758339076, COSV52613899, COSV99895917; called by muse, mutect2, varscan2
- ZNF512B | c.855G>A p.T285= | Silent (SNP) | VAF 33/290 reads (11%) | catalogued as rs557041241, COSV53873476; called by muse, mutect2, varscan2
- ZNF7 | c.1338T>C p.C446= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100296041; called by muse, mutect2, varscan2
- CYP2S1 | c.*76G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100027554; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6048907 C>G | 3'Flank (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99290419; called by muse, mutect2, varscan2
- MIR380 | n.39G>A | RNA (SNP) | VAF 37/103 reads (36%) | catalogued as rs763781233; called by muse, mutect2, varscan2
- TTN | c.10360+1798A>C | Intron (SNP) | VAF 12/97 reads (12%) | catalogued as COSV60139727; called by muse, mutect2, varscan2
